Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AA3A, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AA3A-01A (Primary Tumor).

ICD-O-3

Cholangiocarcinoma & hepatocellular carcinoma
combined 8180h3

Female

Site: Liver C22.0

QJ 3/10/14

DIAGNOSIS:

C. Liver, left lobe and segment VI, resection: Combined hepatocellular and cholangiocarcinoma, grade 4 (of 4) is identified forming a mass (5.8 x 5.3 x 4.0 cm). Microvascular invasion is absent (no vein invasion identified microscopically). A single regional lymph node is negative for tumor. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.1 cm). [AJCC pT1N0MX]. The background non-neoplastic hepatic parenchyma is unremarkable.

A. Lymph node, paracaval, biopsy: One paracaval lymph node is negative for tumor.

B. Lymph node, hepatic artery, biopsy: One hepatic artery lymph node is negative for tumor.

Source: NCI Genomic Data Commons file d9ea6ef8-b045-4a35-b2be-623035a27be5 (TCGA-DD-AA3A.F1055545-91C4-4397-BD34-FE995A3E9B05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).